TARGET case TARGET-40-NAAWFE — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/6c3a6a16-e6c9-5f3b-8ac2-c78230b9accf

Biospecimens (1 sample)
- Sample TARGET-40-NAAWFE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
